Somatic mutation profile of tumor specimen MBCProject_2811_T1_WES (aliquot MBCProject_2811_T1_WES_1) from CMI case MBCProject_2811, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 31.9 years (11,658 days).
Specimen MBCProject_2811_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85a5c784-b9c4-486e-9fe8-7d796e5a7097.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_2811_SALIVA (Saliva), aliquot MBCProject_2811_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/023bc66f-7591-416f-b232-2d2fdf347da4

The open-access MAF lists 47 somatic variants for this specimen: 27 protein-altering or splice-affecting, 13 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 13, Intron 6, Frame Shift Del 1, Nonsense Mutation 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLOD2 | c.1975C>T p.R659* | Nonsense Mutation (SNP) | VAF 24/116 reads (21%) | catalogued as rs780770356, COSV51469342; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 36/233 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587781288, CM993216, COSV52664953, COSV52926626, COSV53155598; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BANK1 | c.562T>C p.S188P | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV59841613; called by muse, mutect2, varscan2
- BFSP2 | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as rs756829125; called by muse, mutect2, varscan2
- COL4A4 | c.2309C>T p.P770L | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs374356930; called by muse, mutect2, varscan2
- EML6 | c.3772G>A p.G1258S | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447995901; called by muse, mutect2, varscan2
- OR2W3 | c.728C>A p.S243Y | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100831628; called by muse, mutect2, varscan2
- SIGLEC1 | c.3184G>A p.E1062K | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as rs774431544; called by muse, mutect2, varscan2
- STOX1 | c.1334G>C p.G445A | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV53814974, COSV53817273; called by muse, varscan2
- TFB2M | c.1102C>G p.Q368E | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs778994953, COSV100830425; called by mutect2, varscan2
- ZNF728 | c.459C>G p.I153M | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as rs559668892, COSV74099239; called by muse, mutect2, varscan2
- AKAP9 | c.611A>G p.D204G | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALDH1L1 | c.2093_2094del p.S698Cfs*23 | Frame Shift Del (DEL) | VAF 23/165 reads (14%) | called by mutect2, pindel, varscan2
- ALS2 | c.2662G>A p.E888K | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- CELA2A | c.523C>G p.Q175E | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- CHD3 | c.4267G>A p.A1423T | Missense Mutation (SNP) | VAF 34/292 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DAZAP1 | c.262dup p.R88Pfs*22 | Frame Shift Ins (INS) | VAF 21/152 reads (14%) | called by mutect2, pindel, varscan2
- DSCAM | c.5013G>C p.E1671D | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- GDI2 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 23/244 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.397); called by muse, mutect2
- GMEB1 | c.676G>C p.G226R | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- GRIN2D | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 34/239 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- KCNN2 | c.846T>A p.D282E (on ENST00000264773; = p.D494E on NM_021614.4) | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- NRSN2 | c.473A>G p.H158R | Missense Mutation (SNP) | VAF 55/381 reads (14%) | SIFT tolerated (0.91); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- PHC1 | c.2465C>A p.T822N | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- RETNLB | c.220A>C p.T74P | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM14 | c.224G>C p.C75S | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, mutect2
- VENTX | c.547C>A p.L183M | Missense Mutation (SNP) | VAF 77/362 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- ABCA2 | c.2199C>T p.V733= (on ENST00000614293; = p.V703= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/292 reads (15%) | catalogued as rs1004181569; called by muse, mutect2, varscan2
- ADAM19 | c.933C>T p.I311= | Silent (SNP) | VAF 47/247 reads (19%) | catalogued as rs550550364, COSV99977896; called by muse, mutect2, varscan2
- BSN | c.8403G>C p.L2801= | Silent (SNP) | VAF 12/89 reads (13%) | called by muse, mutect2, varscan2
- COL6A3 | c.3330C>T p.A1110= | Silent (SNP) | VAF 13/115 reads (11%) | catalogued as rs111328076; called by mutect2, varscan2
- EPHB2 | c.1812C>T p.D604= (on ENST00000400191 / NM_001309193.2; = p.D605= on NM_004442.7) | Silent (SNP) | VAF 27/145 reads (19%) | catalogued as rs1208361026, COSV65865777; called by muse, mutect2, varscan2
- FLNA | c.4905T>C p.R1635= | Silent (SNP) | VAF 18/137 reads (13%) | called by muse, mutect2, varscan2
- GCC2 | c.1680C>T p.T560= | Silent (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- GPD1 | c.813G>A p.R271= | Silent (SNP) | VAF 35/305 reads (11%) | called by muse, mutect2, varscan2
- GPIHBP1 | c.360G>A p.T120= | Silent (SNP) | VAF 69/509 reads (14%) | catalogued as rs779774750, COSV58209645; called by muse, mutect2, varscan2
- GRIN3A | c.1863G>A p.L621= | Silent (SNP) | VAF 18/186 reads (10%) | called by muse, mutect2
- LRP4 | c.1059G>C p.T353= | Silent (SNP) | VAF 47/323 reads (15%) | called by muse, mutect2, varscan2
- NPHS1 | c.2901G>T p.G967= | Silent (SNP) | VAF 16/118 reads (14%) | called by muse, mutect2, varscan2
- STN1 | c.153A>C p.G51= | Silent (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- ABI3BP | c.1064-493A>C | Intron (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2, varscan2
- ARHGAP27P2 | n.171C>G | RNA (SNP) | VAF 26/314 reads (8%) | called by muse, mutect2
- LYRM4 | c.208-34697T>C | Intron (SNP) | VAF 39/195 reads (20%) | catalogued as rs750032198; called by muse, mutect2, varscan2
- PITX2 | c.390+199C>T | Intron (SNP) | VAF 22/141 reads (16%) | called by muse, mutect2, varscan2
- PTPRR | c.628-35C>T | Intron (SNP) | VAF 13/76 reads (17%) | catalogued as rs776971192; called by muse, mutect2, varscan2
- RPL27A | c.319-229G>C | Intron (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- RUSC1 | c.1358-381C>A | Intron (SNP) | VAF 19/204 reads (9%) | catalogued as COSV52738798; called by muse, mutect2
